Surgical pathology report (de-identified scan), TCGA case TCGA-55-7573, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7573-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Lung, right upper lobe, lobectomy:

Tumor characteristics:

1. Histologic type: adenocarcinoma.
2. Histologic grade: 2 (moderately differentiated).
3. Tumor site: Subpleural.
4. Tumor focality: Unifocal.
5. Tumor size: 2.5 x 1.5 x 1.5 cm.
6. Visceral tumor invasion: No
7. Lymphovascular space invasion: Not identified.
8. Tumor extension not applicable.
9. Treatment effect not applicable.

Surgical Margin Status:

1. Tumor distance from bronchial margin: greater than 1 cm.
2. Tumor distance from parenchymal stapled margin: less than 0.1 cm (see comment).
3. Tumor distance from pleural surface: 0.4 cm.

Lymph node status:

1. Total number of lymph nodes received (includes part B below): Seven.
2. Number containing metastatic carcinoma: Zero.

Other significant findings:

1. pTNM stage: pT1b,N0.

B. Lymph node, level 9, excision:

Negative for malignancy, one node.

Electronic Signature: [REDACTED]

COMMENTS:

The patient's history of prior renal cell carcinoma is noted. There is, however, no material identified in our files for review and comparison. Accordingly, a limited series of immunohistochemical stains is performed on a representative block of a malignancy. Sections are examined along with appropriately staining positive and negative controls, with the following results:

CK7- Positive.
CK20 - Negative.
TTF1- Positive.
RCC- Negative.

Histologically, the malignancy does not resemble a typical renal cell carcinoma, and the staining pattern above essentially excludes the possibility of a metastasis from the kidney, and is typical of a primary pulmonary adenocarcinoma.

The malignancy grossly approaches the stapled parenchymal surgical margin to within less than 0.1 cm. Following removal of the staple line, the inked margin in this site is involved by malignancy. It is noted, however, that the nature of the stapling procedure itself precludes sampling of the true final surgical margin. Clinical correlation is suggested.

[page 2 of 2]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: [REDACTED] female with history of renal cell carcinoma, with a right upper lobe lesion suspicious for non-small cell carcinoma of the lung

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right upper lobe
- B. Level 9 lymph node

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in two formalin-filled containers labeled with the patient's name.

A. Container A is additionally labeled "right upper lobe," and contains a 16.0 x 8.5 x 2.8 cm, lung lobe. The pleura is purple-pink, moderately anthracotic and glistening. A 10.0 x 3.5 cm, area of exposed red-pink mucosa is present. Within this area are multiple exposed segments of bronchi and vasculature. Extending from both ends of this area are two serpiginous staple lines, each measuring 5.5 cm in greatest dimension. The staple line is removed and the underlying parenchyma is inked black. Additionally, the exposed bronchi and vascular margins are taken en face, and the exposed parenchyma is also inked black. The bronchi feature yellow-tan, striated endothelium with no discrete lesions. Sectioning reveals a 2.5 x 1.5 x 1.5 cm, well circumscribed, yellow-tan, firm glistening mass that resides 0.4 cm below the blue-inked pleura, and approaches to within less than 0.1 cm of the closest stapled parenchymal margin. The remainder of the cut surface is pink-tan and focally congested. No additional lesions are identified. Seven ill-defined black anthracotic nodules are identified consistent with parabrachial lymph nodes. They range from 0.1 up to 0.3 cm in greatest dimension. Representative sections are submitted in cassettes A1-8, labeled [REDACTED] designated as follows: 1 -- bronchial and vascular margins, en face; 2-3 -- mass to inked parenchymal margin, perpendicular; 4-5 -- sections to include mass, closest inked parenchymal margin, and inked pleura (perpendicular); 6 -- remainder of mass to inked pleura, perpendicular; 7 -- most normal-appearing parenchyma; 8 -- aggregate of whole possible lymph nodes.

Additionally, a yellow, a green and a blue cassette are submitted with this part, all labeled [REDACTED]

B. Container B is additionally labeled level 9 lymph node and contains a 0.7 x 0.7 x 0.6 cm, gray-black, nodule consistent with anthracotic lymph node. The specimen is bisected and entirely submitted in cassette B, labeled [REDACTED]

Source: NCI Genomic Data Commons file 36094254-b862-4e30-b0bc-a56df4d0406e (TCGA-55-7573.3EDA2065-31DA-49D1-8974-9D004ED26113.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).